Somatic mutation profile of tumor specimen TARGET-10-PARPRW-03A (aliquot TARGET-10-PARPRW-03A-01D) from TARGET case TARGET-10-PARPRW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,479 days).
Specimen TARGET-10-PARPRW-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffbc491d-d115-448a-8805-0acbf4dd534e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPRW-10A (Blood Derived Normal), aliquot TARGET-10-PARPRW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/958ed88d-e48f-476d-8261-57d594946470

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCGBP | c.4741C>T p.P1581S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55450144; called by muse, mutect2, varscan2
- HLF | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56831389; called by muse, mutect2, varscan2
- MID1 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV58198170; called by muse, mutect2, varscan2
- NOTCH3 | c.5252C>A p.T1751N | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54644877; called by muse, mutect2, varscan2
- RXFP2 | c.1676A>C p.N559T | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV53639592; called by muse, mutect2, varscan2
- SUPT6H | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV58928372; called by muse, mutect2, varscan2
- TCF3 | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.172); catalogued as COSV53652434; called by muse, varscan2
- ZNF257 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV71306564; called by muse, mutect2, varscan2
- CDK16 | c.700_701insGGGCGTA p.K234Rfs*3 | Frame Shift Ins (INS) | VAF 66/232 reads (28%) | called by mutect2, pindel, varscan2
- TCF3 | c.1409del p.G470Afs*16 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | called by pindel, varscan2
- TRAJ28 | c.1_5delinsGTG p.Y2Vfs*? | Frame Shift Del (DEL) | VAF 102/165 reads (62%) | called by pindel, varscan2*
- ZRANB1 | c.2119_2127del p.D707_*709delext*71 | Nonstop Mutation (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- FAM184A | c.2475C>A p.L825= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as COSV58855930, COSV58857521; called by muse, mutect2, varscan2
- GRN | c.969C>T p.P323= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as rs749575144, COSV50008486; called by muse, mutect2, varscan2
- ZMIZ2 | c.267G>A p.L89= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV54810311; called by muse, mutect2, varscan2
